Gene-level copy-number profile of tumor specimen TCGA-19-5950-01A from TCGA case TCGA-19-5950, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.7 years (19,244 days).
Specimen TCGA-19-5950-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.3cf203fa-ff07-4ac2-b760-bf292076ee66.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-19-5950-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7eefbb8b-2b3e-431d-9b54-9dd814859b86

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 3,143; copy number 2: 48,797; copy number 3: 7,798; copy number 4: 16; copy number 6: 1; copy number 7: 5; copy number 8: 5; copy number 35: 12; copy number 45: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-19-5950-01A-11D-1694-01): tumor purity 0.84, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,331,446–21,160,336, 17 genes: AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B, HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA.
- chr9:21,994,139–22,128,103, 1 gene (within-gene range 0–1): CDKN2B-AS1.
- chr9:22,002,903–23,438,700, 11 genes (within-gene range 0–1): CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1.
- chr9:25,088,811–25,938,434, 5 genes: RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:39,287,456–39,366,375, 1 gene, copy number 8 (within-gene range 2–8): RFC1.
- chr4:39,399,149–39,458,931, 5 genes, copy number 7–8: RNU6-887P, KLB, MIR5591, Y_RNA, RPL9.
- chr4:42,281,830–42,402,487, 2 genes, copy number 8 (within-gene range 2–8): AC024022.1, SHISA3.
- chr4:42,657,496–42,707,335, 2 genes, copy number 7: AC096734.2, AC096734.1.
- chr7:54,419,444–55,260,256, 16 genes, copy number 35–45: SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr9:1,540,321–1,550,103, 1 gene, copy number 6: AL358053.1.

Autosomal genes at a single copy (total copy number 1): 3,143. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
